Somatic mutation profile of tumor specimen TARGET-20-PATBPW-09A (aliquot TARGET-20-PATBPW-09A-01D) from TARGET case TARGET-20-PATBPW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (719 days).
Specimen TARGET-20-PATBPW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) baeacbda-1b59-4377-ab6e-896c75677501.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATBPW-14A (Bone Marrow Normal), aliquot TARGET-20-PATBPW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83155eb7-03d1-49ec-a158-60c6455754f2

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.121); catalogued as rs724159947, CM150819, COSV67147991; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3916C>T p.R1306* | Nonsense Mutation (SNP) | VAF 61/93 reads (66%) | catalogued as rs376576925, CM981381, COSV62193951; ClinVar: pathogenic; called by muse, mutect2, varscan2
